Somatic mutation profile of tumor specimen MBCProject_0105_T1_WES (aliquot MBCProject_0105_T1_WES_1) from CMI case MBCProject_0105, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 39.3 years (14,367 days).
Specimen MBCProject_0105_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9b4b240-1916-4822-b52a-dfcf230ae025.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0105_SALIVA (Saliva), aliquot MBCProject_0105_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a83629-3be4-4672-915c-4c02c36e8e7b

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POLG | c.3286C>T p.R1096C | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs201732356, CM030941, COSV99174821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ALX1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1167995672; called by muse, mutect2, varscan2
- COL6A3 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1386395959; called by muse, mutect2
- CUX2 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs749241101, COSV55648455; called by muse, varscan2
- HMCN1 | c.3385T>A p.F1129I | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.968); catalogued as COSV54878709; called by muse, mutect2
- TRIT1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140406438; called by muse, mutect2, varscan2
- ZNF658 | c.1997C>A p.S666Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as rs769891429; called by mutect2, varscan2
- EPN2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 46/700 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KRT12 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 26/732 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); called by muse, mutect2
- N4BP2 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- SACS | c.7570C>T p.Q2524* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- SIGLEC10 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 33/531 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- WDR20 | c.211del p.R71Gfs*17 | Frame Shift Del (DEL) | VAF 68/648 reads (10%) | called by mutect2, varscan2
- MGAT5B | c.1368C>T p.G456= | Silent (SNP) | VAF 104/464 reads (22%) | catalogued as rs780443392; called by muse, mutect2, varscan2
- TACC2 | c.3189G>A p.L1063= | Silent (SNP) | VAF 70/608 reads (12%) | called by muse, mutect2, varscan2
- ITGA6 | c.3232-2282A>T | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- SSPOP | n.13883G>T | RNA (SNP) | VAF 35/393 reads (9%) | called by muse, mutect2
